Somatic mutation profile of tumor specimen TCGA-EL-A3GV-01A (aliquot TCGA-EL-A3GV-01A-11D-A21A-08) from TCGA case TCGA-EL-A3GV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 65.1 years (23,787 days).
Specimen TCGA-EL-A3GV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dde4d0c-92be-4431-be1e-674c016b4d59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GV-10A (Blood Derived Normal), aliquot TCGA-EL-A3GV-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/508bef1c-26cc-4709-93e7-555d69d934a5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARSF | c.683T>A p.L228H | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63840575; called by muse, mutect2
- ATRX | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV64880935; called by muse, mutect2
- CEP192 | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV58068462; called by muse, mutect2
- CNGB1 | c.2615T>C p.F872S | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV51904668; called by muse, mutect2
- KIF27 | c.3120A>T p.K1040N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV52830152; called by muse, mutect2
- NF1 | c.4703A>G p.K1568R (on ENST00000358273 / NM_001042492.3; = p.K1547R on NM_000267.3) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as CD111466, COSV62213877; called by muse, mutect2
- TRIML1 | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV60194018, COSV60196036; called by muse, mutect2
- UNC93A | c.1278G>A p.G426= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as COSV57810066; called by muse, mutect2
